Somatic mutation profile of tumor specimen TARGET-30-PARDCK-01A (aliquot TARGET-30-PARDCK-01A-01D) from TARGET case TARGET-30-PARDCK, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.6 years (2,060 days).
Specimen TARGET-30-PARDCK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3a61324-2f21-4503-94d7-02c8639e8b45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARDCK-10A (Blood Derived Normal), aliquot TARGET-30-PARDCK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0657e4b3-7bfc-48e0-a818-796f5c03bca3

The open-access MAF lists 53 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 40, Silent 10, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB2 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs372274381, COSV100279170; called by muse, mutect2, varscan2
- ATP8B1 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs1261063802, COSV52180014; called by muse, mutect2, varscan2
- ATRX | c.2968G>T p.E990* | Nonsense Mutation (SNP) | VAF 93/207 reads (45%) | catalogued as COSV64883057; called by muse, mutect2, varscan2
- C5AR2 | c.272C>A p.A91E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV57257258; called by muse, mutect2, varscan2
- CCDC40 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs780647441, COSV53904438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLINT1 | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs752606665, COSV51628851; called by muse, mutect2, varscan2
- CYP46A1 | c.1037A>T p.D346V | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55896524; called by muse, mutect2, varscan2
- EOMES | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55415419; called by muse, mutect2
- ERN2 | c.1248T>A p.H416Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56837789; called by muse, mutect2, varscan2
- FAT2 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55828971; called by muse, mutect2, varscan2
- HNRNPU | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.092); catalogued as COSV51694132; called by muse, mutect2, varscan2
- HOXB5 | c.395A>C p.E132A | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as rs756393035, COSV53314209; called by muse, mutect2, varscan2
- IQCF1 | c.608T>A p.I203K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV58824066; called by muse, mutect2, varscan2
- MAGEA3 | c.491T>G p.I164S | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64756501; called by muse, mutect2, varscan2
- MPND | c.625A>G p.R209G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV53659719; called by muse, mutect2, varscan2
- MSI2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as COSV52367561; called by muse, mutect2, varscan2
- NEIL3 | c.1661G>T p.C554F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52813524; called by muse, mutect2, varscan2
- NLRP11 | c.2548C>A p.Q850K | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.053); catalogued as COSV64085864, COSV64088751; called by muse, mutect2, varscan2
- NLRP11 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.071); catalogued as rs74865045, COSV64086685, COSV64088753; called by muse, mutect2, varscan2
- PI4KA | c.4636C>T p.L1546F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55422433; called by muse, mutect2, varscan2
- PIKFYVE | c.4386G>T p.K1462N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV52248790; called by muse, mutect2, varscan2
- POLR2A | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548638112; called by muse, mutect2, varscan2
- PRKCG | c.1617G>T p.W539C | Missense Mutation (SNP) | VAF 128/333 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54732632; called by muse, mutect2, varscan2
- PRSS16 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.094); catalogued as COSV57916849; called by muse, mutect2
- PRX | c.3205G>T p.A1069S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.028); catalogued as COSV52525386; called by muse, mutect2, varscan2
- PSMC3 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54082747; called by muse, mutect2, varscan2
- SASH1 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66565718; called by muse, mutect2, varscan2
- SLC4A3 | c.2063A>T p.D688V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559202498, COSV56097418; called by muse, mutect2, varscan2
- ST3GAL2 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 27/182 reads (15%) | PolyPhen probably damaging (0.932); catalogued as rs756779019, COSV61596669; called by muse, mutect2, varscan2
- STAG1 | c.2882T>G p.L961R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52623397; called by muse, mutect2, varscan2
- STX5 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53681845; called by muse, mutect2, varscan2
- TOP1MT | c.796A>T p.N266Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100239561; called by muse, mutect2, varscan2
- TRIO | c.3634G>T p.A1212S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV60094916; called by muse, mutect2, varscan2
- UBQLNL | c.74A>T p.N25I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV66494539; called by muse, mutect2, varscan2
- VNN1 | c.200C>A p.A67E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63391005; called by muse, mutect2, varscan2
- ZFHX4 | c.6409A>T p.T2137S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV51494754; called by muse, mutect2, varscan2
- ZNF233 | c.891C>G p.Y297* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV61934683; called by muse, mutect2, varscan2
- ZNF543 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58626775; called by muse, mutect2, varscan2
- FRMD7 | c.1995G>C p.L665F | Missense Mutation (SNP) | VAF 5/124 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- NBPF10 | c.1072A>C p.K358Q | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- OR4K2 | c.118G>C p.V40L | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR8I2 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- RHOXF2 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by mutect2, varscan2
- ADAM28 | c.33C>A p.L11= | Silent (SNP) | VAF 57/121 reads (47%) | catalogued as COSV56105176; called by muse, mutect2, varscan2
- MAGEC3 | c.1674A>T p.I558= | Silent (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2
- MAGOHB | c.21C>T p.F7= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV57898141; called by muse, mutect2
- MUC5B | c.8931C>T p.T2977= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV71595301, COSV71595709; called by muse, mutect2, varscan2
- NPEPL1 | c.582C>T p.T194= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs757775025, COSV61940581; called by muse, mutect2, varscan2
- OR1J2 | c.216C>A p.S72= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV58945163, COSV58945269; called by muse, mutect2, varscan2
- OR4X1 | c.39G>T p.V13= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV60723827; called by muse, mutect2, varscan2
- TATDN2 | c.654C>A p.P218= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV55054008; called by muse, mutect2, varscan2
- TMPRSS6 | c.2232C>T p.G744= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV60983587; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.589C>A p.R197= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV59528446, COSV59529469; called by muse, mutect2, varscan2
